Somatic mutation profile of tumor specimen ALCH-B79J-TTP1-A (aliquot ALCH-B79J-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B79J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 29.6 years (10,815 days).
Specimen ALCH-B79J-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e189d62-86f7-45b7-9ac4-c4ff968c7005.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B79J-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B79J-NB1-A-1-0-D-A96Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9270796b-2053-47a1-80ea-df7de69052b7

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Del 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL13A1 | c.1436G>A p.G479E (on ENST00000398978 / NM_001130103.2; = p.G422E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62569031; called by muse, mutect2
- INSM1 | c.979del p.R327Afs*74 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as COSV59604708; called by mutect2, pindel, varscan2
- NLRC5 | c.2933G>A p.R978K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99348188; called by muse, mutect2
- BMS1 | c.3088A>G p.T1030A | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); called by muse, mutect2
- BTN3A1 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HBD | c.172A>G p.N58D | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MAGI1 | c.2440A>G p.I814V (on ENST00000402939 / NM_001033057.2; = p.I842V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2
- MAP3K15 | c.3929A>G p.K1310R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR3C2 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- NUP62 | c.994C>G p.Q332E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SH3TC1 | c.2752_2764del p.A918Pfs*222 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel, varscan2
- SOBP | c.2339_2340del p.C780Sfs*27 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- AR | c.843C>T p.P281= | Silent (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- CATSPERD | c.1113G>A p.V371= | Silent (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- DLG1 | c.2436A>C p.G812= (on ENST00000419354 / NM_001290983.1; = p.G834= on NM_004087.2) | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- SAMD9 | c.3396A>G p.R1132= | Silent (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- TP53BP1 | c.39T>C p.S13= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs548813162; called by muse, mutect2
- CEP290 | c.1824+650C>T | Intron (SNP) | VAF 25/287 reads (9%) | called by muse, mutect2
- IGFN1 | c.1242-1080G>A | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
